Somatic mutation profile of tumor specimen TCGA-MA-AA42-01A (aliquot TCGA-MA-AA42-01A-12D-A387-09) from TCGA case TCGA-MA-AA42, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 75.2 years (27,460 days).
Specimen TCGA-MA-AA42-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) beefd231-c271-4f17-98f1-a17a6adf2c41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MA-AA42-10A (Blood Derived Normal), aliquot TCGA-MA-AA42-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4220a1c-8a3a-46d8-93f0-a8ec230e9e59

The open-access MAF lists 561 somatic variants for this specimen: 409 protein-altering or splice-affecting, 137 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 312, Silent 137, Frame Shift Del 47, Nonsense Mutation 17, Frame Shift Ins 14, Splice Site 9, Intron 7, In Frame Del 7, 3'UTR 5, Splice Region 3, 5'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 20/94 reads (21%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- AARS1 | c.731T>G p.L244R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99933637; called by muse, mutect2, varscan2
- ACSM3 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99184754; called by muse, mutect2
- ACTL6B | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50515385; called by muse, mutect2, varscan2
- ACTRT1 | c.272A>G p.H91R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100947678, COSV64419034, COSV64420066; called by muse, mutect2, varscan2
- ADAMTS12 | c.4648C>G p.Q1550E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.931); catalogued as COSV100711393; called by muse, mutect2, varscan2
- ADAMTS2 | c.920T>C p.L307S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99202560; called by muse, mutect2, varscan2
- ADGRA3 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as rs564893051, COSV99293512; called by muse, mutect2, varscan2
- ADGRL1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs370477888; called by muse, mutect2, varscan2
- ADORA1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs146812291; called by muse, mutect2, varscan2
- AFDN | c.4858C>T p.R1620C (on ENST00000447894 / NM_001366320.1; = p.R1618C on NM_001040000.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV60039779; called by muse, mutect2, varscan2
- AGXT | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as rs761622783, COSV100280188, COSV56753793; called by muse, mutect2, varscan2
- AHNAK | c.3439G>A p.D1147N | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV99948531; called by muse, mutect2, varscan2
- AKAP4 | c.2167G>C p.E723Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV100654318; called by muse, mutect2, varscan2
- AKIRIN1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as rs753878747, COSV65909876, COSV65910397; called by muse, mutect2, varscan2
- ALAS1 | c.1241A>T p.H414L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100050425; called by muse, mutect2, varscan2
- ALDH1L1 | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1333230358, COSV56417478, COSV99857204; called by muse, mutect2, varscan2
- ALOX15B | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.773); catalogued as rs1454749957, COSV101205653; called by muse, mutect2, varscan2
- ALOX15B | c.1670G>A p.S557N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101205655; called by muse, mutect2, varscan2
- ALPG | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV99779403; called by muse, mutect2, varscan2
- ALPK2 | c.5044A>G p.K1682E | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs764675989, COSV100864560; called by muse, mutect2, varscan2
- AMER1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100366731, COSV57664045, COSV57669127; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 19/38 reads (50%) | catalogued as rs34047276; called by mutect2, varscan2
- ANGPT2 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100291058; called by muse, mutect2
- ANKLE2 | c.2483G>A p.G828E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100514250; called by muse, varscan2
- ANO2 | c.1957G>A p.V653I (on ENST00000356134 / NM_001278597.3; = p.V657I on NM_001278596.3) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs755546576, COSV100501659; called by muse, mutect2, varscan2
- ANO9 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as rs1208623251, COSV60382945; called by muse, mutect2
- AOC3 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53824571; called by muse, mutect2
- ARAP2 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs749795521, COSV58283421; called by muse, mutect2, varscan2
- ARHGEF11 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs746265259, COSV100810291; called by muse, mutect2, varscan2
- ARHGEF2 | c.416G>A p.R139H (on ENST00000361247 / NM_001162383.2; = p.R112H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs374781823; called by muse, mutect2, varscan2
- ARPC2 | c.74+1G>C p.X25_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99826787; called by muse, mutect2, varscan2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | catalogued as rs749460467; called by mutect2, pindel, varscan2
- ASB4 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100367234; called by muse, mutect2, varscan2
- ASH1L | c.2809G>C p.E937Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100853522; called by muse, mutect2, varscan2
- ASIC2 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1481256687, COSV63314312; called by muse, mutect2, varscan2
- ASPA | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99559273; called by muse, mutect2, varscan2
- ATAD5 | c.4896_4898del p.T1633del | In Frame Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs777761769; called by pindel, varscan2
- ATG10 | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99967089; called by muse, mutect2, varscan2
- ATG7 | c.411+1G>A p.X137_splice | Splice Site (SNP) | VAF 20/41 reads (49%) | catalogued as rs1168083997, COSV100607651; called by muse, mutect2, varscan2
- ATP11A | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs780037254, COSV99369340; called by muse, mutect2, varscan2
- ATRN | c.3322+1G>A p.X1108_splice | Splice Site (SNP) | VAF 6/84 reads (7%) | catalogued as rs1251355617, COSV53530267, COSV53531674; called by muse, mutect2
- AWAT1 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV100997222, COSV65738268; called by muse, mutect2, varscan2
- B3GNT6 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); catalogued as COSV62829237; called by muse, mutect2, varscan2
- BAG6 | c.1661G>A p.R554Q (on ENST00000676571; = p.R507Q on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.607); catalogued as rs1166716977, COSV52987683; called by muse, mutect2
- BCAS1 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.301); catalogued as rs752495014, COSV65085414; called by muse, mutect2, varscan2
- BICD1 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.198); catalogued as rs757213231, COSV55684127, COSV99862626, COSV99863061; called by mutect2, varscan2
- BLM | c.3173A>G p.H1058R | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100757266; called by muse, mutect2, varscan2
- BOP1 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1419258074; called by muse, mutect2, varscan2
- C1orf174 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as rs140673232; called by muse, mutect2, varscan2
- C2orf16 | c.5947A>G p.T1983A | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV100820887; called by muse, mutect2
- CACHD1 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs915706137, COSV51553672; called by muse, mutect2, varscan2
- CACNB2 | c.1829G>A p.R610Q (on ENST00000324631 / NM_201596.3; = p.R555Q on NM_000724.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.079); catalogued as rs781454884, COSV56637779; called by mutect2, varscan2
- CARMIL3 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs368259708; called by muse, mutect2, varscan2
- CCDC190 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as rs976901171, COSV63362998; called by muse, mutect2
- CCDC33 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs762588978, COSV99173389; called by muse, mutect2, varscan2
- CCDC97 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.303); catalogued as rs372224178; called by muse, mutect2, varscan2
- CDC37 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs751173951, COSV99705824; called by muse, mutect2
- CDC5L | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs141102915; called by muse, mutect2, varscan2
- CDC73 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs878855091, COSV66468152; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV100052296; called by muse, mutect2
- CEACAM8 | c.777C>A p.C259* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99747719; called by muse, mutect2, varscan2
- CENPF | c.8105G>A p.R2702Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1368085730, COSV100871816; called by muse, mutect2, varscan2
- CEP170 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100317489; called by mutect2, varscan2
- CES1 | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV100828742; called by muse, mutect2, varscan2
- CFAP65 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as rs773825950, COSV55389267, COSV55389791; called by muse, mutect2, varscan2
- CHD6 | c.3751G>A p.A1251T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV100498509; called by muse, mutect2, varscan2
- CHD8 | c.7112del p.N2371Ifs*6 (on ENST00000646647 / NM_001170629.2; = p.N2092Ifs*6 on NM_020920.4) | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as rs751094013; called by mutect2, varscan2
- CHML | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV100087610; called by muse, mutect2, varscan2
- CHMP6 | c.404A>C p.E135A | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.067); catalogued as COSV100289500, COSV57327269; called by muse, mutect2, varscan2
- CIDEA | c.38+2C>T p.X13_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as COSV57598727; called by mutect2, varscan2
- CLCNKB | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as rs1399039201, COSV65161768; called by muse, mutect2
- CLDND2 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99389915; called by muse, mutect2, varscan2
- COL7A1 | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs1559427559, COSV100096948; called by muse, mutect2, varscan2
- COLGALT1 | c.859_861del p.E287del | In Frame Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs759310603; called by pindel, varscan2
- CP | c.1891C>G p.Q631E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV52830332, COSV99224288; called by muse, mutect2, varscan2
- CPSF4 | c.358A>C p.K120Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99462545; called by muse, mutect2, varscan2
- CR2 | c.1538T>A p.I513N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.157); catalogued as COSV100889681; called by muse, mutect2, varscan2
- CRACD | c.3077G>A p.G1026E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99949671; called by muse, mutect2, varscan2
- CREBBP | c.4990C>T p.R1664C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52114474; called by muse, mutect2, varscan2
- CRYGC | c.67T>C p.C23R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as COSV99965349; called by muse, mutect2, varscan2
- CSAD | c.1330C>T p.R444C (on ENST00000444623 / NM_001244705.2; = p.R471C on NM_015989.5) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs374597733, COSV99914805; called by muse, mutect2, varscan2
- CSMD3 | c.5035C>T p.R1679W (on ENST00000297405 / NM_001363185.1; = p.R1575W on NM_052900.3) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368685063, COSV52136628; called by muse, mutect2, varscan2
- CUBN | c.7891G>C p.D2631H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100913110; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs751187768; called by mutect2, varscan2
- DCC | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs543242235, COSV59091535; called by muse, mutect2, varscan2
- DCC | c.3640G>C p.G1214R | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV101473363; called by muse, mutect2, varscan2
- DCHS1 | c.3529T>C p.Y1177H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.069); catalogued as COSV100202311; called by muse, mutect2, varscan2
- DCHS1 | c.3238G>T p.A1080S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.133); catalogued as COSV100202312; called by muse, mutect2, varscan2
- DCLK1 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs769128085, COSV55169876; called by muse, mutect2, varscan2
- DDX47 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as rs375924024; called by muse, mutect2, varscan2
- DDX54 | c.1281C>T p.G427= | Splice Region (SNP) | VAF 4/36 reads (11%) | catalogued as COSV58373433; called by muse, varscan2
- DDX58 | c.63C>G p.D21E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.23); catalogued as COSV101153065; called by muse, mutect2, varscan2
- DGKK | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs373977703, COSV65708353; called by muse, mutect2, varscan2
- DHRS7C | c.738C>G p.F246L (on ENST00000330255 / NM_001220493.2; = p.F245L on NM_001105571.3) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV100364821; called by muse, mutect2, varscan2
- DIP2A | c.4456G>A p.A1486T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as rs1451242532, COSV59486463; called by muse, mutect2, varscan2
- DMAC2 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781788109, COSV99700505; called by muse, mutect2, varscan2
- DMD | c.3028G>T p.A1010S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as rs766325631, COSV100821226, COSV63795138; called by muse, mutect2, varscan2
- DNAI2 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs1162547725, COSV56763303; called by muse, mutect2, varscan2
- DNAJB6 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100055784; called by muse, mutect2, varscan2
- DOCK10 | c.1934T>C p.M645T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99290609; called by muse, mutect2, varscan2
- DOCK2 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as rs764590955, COSV99913952; called by muse, mutect2, varscan2
- DOCK4 | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV70313674; called by muse, mutect2
- DSC2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs775614779, COSV51862833; called by muse, mutect2, varscan2
- DSCAM | c.2310C>G p.N770K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101260929; called by muse, mutect2, varscan2
- DSG1 | c.1234C>A p.L412M | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV99936253; called by muse, mutect2
- DYSF | c.4024C>T p.R1342W | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199870606, CM116696, COSV99244545; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- EHD2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs1028265447, COSV99622099; called by muse, mutect2
- EP400 | c.7448C>T p.A2483V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100201734; called by muse, mutect2, varscan2
- ERBB4 | c.3382T>C p.Y1128H | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100726543; called by muse, mutect2
- ERCC4 | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748870665, COSV100319007; called by muse, mutect2, varscan2
- ERN1 | c.2417G>A p.R806H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs775768349, COSV101458482; called by muse, mutect2, varscan2
- ESPL1 | c.5515C>A p.L1839M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375540909; called by muse, mutect2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs771840153, COSV99623995; called by mutect2, varscan2
- EXOC8 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99149935; called by muse, mutect2, varscan2
- EXPH5 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV99761920; called by muse, mutect2, varscan2
- EZHIP | c.1007G>A p.S336N | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as COSV100539802; called by muse, mutect2
- FAM171B | c.357C>A p.S119R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100488811; called by muse, mutect2, varscan2
- FAM199X | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100245555, COSV55434473; called by muse, mutect2, varscan2
- FAM83H | c.3142A>G p.S1048G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV100568004; called by muse, varscan2
- FBN2 | c.4867C>T p.P1623S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as rs139830237, COSV99329108; called by muse, mutect2, varscan2
- FBXW7 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as rs781123562, COSV55916781; called by muse, mutect2, varscan2
- FGF3 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs369755339, COSV100490136; called by muse, mutect2, varscan2
- FIZ1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs1369127960, COSV99684590; called by muse, mutect2, varscan2
- FMR1NB | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs375204379, COSV100975578; called by muse, mutect2, varscan2
- FRY | c.1006T>C p.C336R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100969596; called by muse, mutect2, varscan2
- FRYL | c.6792G>T p.K2264N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.261); catalogued as COSV51958406, COSV99977520; called by muse, mutect2, varscan2
- FSCN1 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100435239; called by muse, mutect2, varscan2
- FTHL17 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100784357, COSV63267036; called by muse, mutect2, varscan2
- GGA2 | c.296G>T p.S99I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV100564789; called by muse, mutect2, varscan2
- GJD4 | c.475del p.A159Pfs*39 | Frame Shift Del (DEL) | VAF 19/38 reads (50%) | catalogued as COSV100397106, COSV58702466; called by mutect2, pindel, varscan2
- GNA15 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.937); catalogued as rs760016259, COSV99505299; called by muse, mutect2, varscan2
- GPC5 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100994930; called by muse, mutect2, varscan2
- GPR162 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1435577824, COSV50593139; called by muse, mutect2, varscan2
- GPRASP1 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100851037; called by muse, mutect2, varscan2
- GREM2 | c.303C>A p.C101* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100547864; called by muse, mutect2, varscan2
- GRM4 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs147191760; called by muse, mutect2, varscan2
- H2BC7 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV100587227, COSV61911476, COSV61912249; called by muse, mutect2, varscan2
- HCAR2 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.23); catalogued as COSV61024690; called by muse, mutect2, varscan2
- HCFC2 | c.710C>A p.T237N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV99983197; called by mutect2, varscan2
- HCN1 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100301331; called by muse, mutect2, varscan2
- HELZ2 | c.2156G>A p.R719H (on ENST00000467148 / NM_001037335.2; = p.R150H on NM_033405.3) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100915416; called by muse, mutect2, varscan2
- HEPH | c.2692G>A p.G898R (on ENST00000343002; = p.G631R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57974893; called by muse, mutect2, varscan2
- HGSNAT | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as rs750824770, COSV52818846; called by muse, mutect2, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 26/150 reads (17%) | catalogued as rs199474609; called by mutect2, varscan2
- HNRNPR | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100164638; called by muse, mutect2, varscan2
- HOXA13 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as rs1562521175, COSV99763650; called by muse, mutect2, varscan2
- HTR3B | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as COSV99492135; called by muse, mutect2, varscan2
- IK | c.1637A>G p.E546G | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.982); catalogued as COSV100845599; called by muse, mutect2, varscan2
- IL12B | c.656A>G p.K219R | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.161); catalogued as COSV99180364; called by muse, mutect2
- IL1RAPL1 | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1285357262, COSV56301315; called by muse, mutect2
- IL3RA | c.818G>C p.R273T | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100452349; called by muse, mutect2, varscan2
- IL6R | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV100690954; called by muse, mutect2, varscan2
- INSR | c.3322C>T p.H1108Y | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100252818; called by muse, mutect2, varscan2
- INTS2 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.205); catalogued as COSV99248468; called by muse, mutect2, varscan2
- IPO7 | c.2849A>C p.D950A | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101121837; called by muse, mutect2
- IRF2 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs761561042, COSV66928939; called by muse, mutect2, varscan2
- ISL2 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99320781; called by muse, mutect2, varscan2
- ITGA7 | c.2584C>G p.L862V (on ENST00000555728; = p.L818V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.23); catalogued as COSV99149270; called by muse, mutect2, varscan2
- ITGA9 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV99293358; called by muse, mutect2, varscan2
- ITSN2 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.7); catalogued as COSV61947721; called by muse, mutect2, varscan2
- KCNF1 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54462676; called by muse, mutect2, varscan2
- KCNH4 | c.642del p.S215Lfs*62 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | catalogued as COSV99236896; called by pindel, varscan2
- KMT2A | c.10067C>T p.A3356V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs149340870, COSV63283642; called by muse, mutect2, varscan2
- KRIT1 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1480771068, COSV60670506; called by muse, mutect2, varscan2
- KRT81 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs753782485, COSV100576994; called by muse, mutect2, varscan2
- KRTAP10-3 | c.387C>A p.C129* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100554636; called by muse, mutect2
- KY | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as rs750351662, COSV71018091; called by muse, mutect2, varscan2
- LAMA3 | c.5788G>A p.A1930T (on ENST00000313654 / NM_198129.4; = p.A321T on NM_000227.6) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as rs750091395, COSV52529630; called by muse, mutect2, varscan2
- LAMB1 | c.3334C>T p.R1112C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748135611, COSV99741307; called by muse, mutect2, varscan2
- LARP1B | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs201885302; called by muse, mutect2, varscan2
- LHX6 | c.980G>A p.C327Y (on ENST00000373755 / NM_001242334.2; = p.C356Y on NM_014368.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as rs1394481320, COSV100493532; called by muse, mutect2, varscan2
- LILRB1 | c.1449dup p.T484Hfs*67 (on ENST00000427581; = p.T447Hfs*54 on NM_006669.6) | Frame Shift Ins (INS) | VAF 10/99 reads (10%) | catalogued as rs747328267; called by mutect2, pindel
- LIN37 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV50000638; called by muse, mutect2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMNTD2 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99530517; called by muse, mutect2, varscan2
- LOXL3 | c.967C>A p.L323M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV99239809; called by mutect2, varscan2
- LRRC23 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99145273; called by muse, mutect2
- LRRTM2 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs926901603, COSV99217835; called by muse, mutect2, varscan2
- LRWD1 | c.1826G>T p.W609L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99484552; called by muse, mutect2, varscan2
- LSM14B | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs1229215264, COSV99444269; called by muse, mutect2, varscan2
- LTBP4 | c.1652G>A p.R551H (on ENST00000308370 / NM_001042544.1; = p.R514H on NM_003573.2) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV99198704; called by muse, mutect2, varscan2
- LTBP4 | c.3012C>T p.D1004= (on ENST00000308370 / NM_001042544.1; = p.D967= on NM_003573.2) | Splice Region (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99198714; called by muse, mutect2, varscan2
- LYPD5 | c.555C>A p.H185Q (on ENST00000377950 / NM_001031749.3; = p.H142Q on NM_182573.2) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV100935268; called by muse, mutect2, varscan2
- MAGEB10 | c.120del p.S41Lfs*6 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | catalogued as COSV63310963, COSV63312330; called by mutect2, pindel, varscan2
- MAGEC1 | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as rs764837381, COSV99596070; called by muse, mutect2, varscan2
- MANBA | c.1900C>A p.H634N (on ENST00000642252; = p.H588N on NM_005908.4) | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV99898945; called by muse, mutect2, varscan2
- MASP1 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751292648, COSV100536535, COSV100537229; called by muse, mutect2, varscan2
- MCOLN3 | c.401T>C p.L134S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV100352862; called by muse, mutect2, varscan2
- MEFV | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1206762845, COSV54824487, COSV54825840; called by muse, mutect2, varscan2
- MGAT5B | c.1924-1G>T p.X642_splice (on ENST00000569840 / NM_001199172.2; = p.X640_splice on NM_144677.3) | Splice Site (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100047487; called by muse, mutect2, varscan2
- MID1 | c.913T>C p.C305R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100452588; called by muse, mutect2
- MLH1 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as CM1213047, COSV99212543; called by muse, mutect2, varscan2
- MOB2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs1421962801, COSV100326625; called by muse, mutect2, varscan2
- MOV10 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs760074539, COSV100659669; called by muse, mutect2, varscan2
- MRM1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs753006011; called by muse, mutect2, varscan2
- MTCL1 | c.3124G>A p.V1042I (on ENST00000306329 / NM_001378206.1; = p.V723I on NM_015210.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as rs753175340, COSV60412197; called by muse, mutect2, varscan2
- MTHFD2L | c.1033del p.I345Sfs*48 (on ENST00000395759 / NM_001144978.2; = p.I287Sfs*48 on NM_001004346.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs761538540; called by mutect2, pindel, varscan2
- MXRA5 | c.6317C>T p.T2106M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54242882, COSV99476892; called by muse, mutect2, varscan2
- MXRA5 | c.757T>C p.C253R | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99478145; called by muse, mutect2, varscan2
- MYO15A | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as rs767388755, COSV52751423; called by muse, mutect2, varscan2
- MYO7A | c.1708C>T p.R570* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as CM142123, COSV101289302, COSV68684689; called by mutect2, varscan2
- MYOM3 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs187598283, COSV100293291; called by muse, mutect2, varscan2
- N4BP2L2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99912635; called by muse, mutect2, varscan2
- NAA50 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV99568744; called by muse, mutect2, varscan2
- NEDD4L | c.1274C>T p.A425V (on ENST00000400345 / NM_001144967.3; = p.A405V on NM_015277.6) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs748170219, COSV99895806; ClinVar: benign; called by muse, mutect2, varscan2
- NLRC5 | c.3580A>T p.K1194* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV52649578, COSV99347793; called by muse, mutect2, varscan2
- NOTCH2 | c.1594G>C p.D532H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99865508; called by muse, mutect2, varscan2
- NPY1R | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.26); catalogued as rs148479836; called by muse, mutect2, varscan2
- NPY2R | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199805893, COSV100279821, COSV61527814; called by muse, varscan2
- NR1D1 | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99225667; called by muse, mutect2, varscan2
- NR2F2 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV101241117; called by muse, mutect2, varscan2
- NRDC | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1415944883, COSV61402345; called by muse, mutect2
- NRROS | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs990494482, COSV60745817; called by muse, mutect2
- NRXN3 | c.2347C>T p.R783W (on ENST00000335750 / NM_001330195.2; = p.R410W on NM_004796.6) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763997346, COSV59780011; called by muse, mutect2, varscan2
- OR11L1 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.433); catalogued as COSV100869456; called by muse, mutect2, varscan2
- OR1L3 | c.117G>C p.L39F | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV100506279; called by muse, mutect2
- OR1M1 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101447578, COSV70037650; called by muse, mutect2, varscan2
- OR4C16 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs768595930, COSV58940480; called by muse, mutect2, varscan2
- OR52A1 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100200536; called by muse, mutect2, varscan2
- OR6T1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs765590865, COSV100190091, COSV58307265; called by muse, mutect2, varscan2
- OSBPL7 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs755578044, COSV50109039; called by muse, mutect2, varscan2
- PATJ | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs745498341, COSV100334567; called by muse, mutect2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PAXIP1 | c.1927A>G p.T643A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV101249905; called by muse, mutect2, varscan2
- PCDHB15 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.16); catalogued as COSV99179045; called by muse, mutect2, varscan2
- PCDHGB7 | c.2294T>C p.F765S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV53978738, COSV99542467; called by muse, mutect2, varscan2
- PCDHGC3 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV52748765; called by muse, mutect2, varscan2
- PDCD4 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs375978756, COSV99701258; called by muse, mutect2, varscan2
- PDE6B | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV55327946; called by muse, mutect2, varscan2
- PELI1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs761769713, COSV62730817; called by muse, mutect2, varscan2
- PHLDB3 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200179651, COSV52670957; called by muse, mutect2, varscan2
- PIDD1 | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754924901, COSV100204259; called by muse, mutect2, varscan2
- PIGB | c.41dup p.G15Rfs*72 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | catalogued as rs745639719; called by mutect2, pindel, varscan2
- PIGK | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs565004204, COSV63062156; called by muse, mutect2, varscan2
- PIKFYVE | c.5374+2T>C p.X1792_splice | Splice Site (SNP) | VAF 5/59 reads (8%) | catalogued as COSV100011113; called by muse, mutect2, varscan2
- PIP5K1B | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV99599354; called by muse, mutect2, varscan2
- PISD | c.350G>A p.R117H (on ENST00000439502 / NM_001326412.1; = p.R83H on NM_014338.3) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1310303080, COSV99837328; called by muse, mutect2, varscan2
- PLCE1 | c.5622+2T>C p.X1874_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99596039; called by muse, mutect2, varscan2
- PLD5 | c.932C>T p.S311L (on ENST00000442594; = p.S249L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs967938870, COSV59144728; called by muse, mutect2, varscan2
- PLEKHN1 | c.1063G>A p.E355K (on ENST00000379409; = p.E303K on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs150711457; called by muse, mutect2, varscan2
- PLTP | c.191_193del p.N64del | In Frame Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs761925325; called by pindel, varscan2
- PLXNA1 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.304); catalogued as rs762279605, COSV99303664; called by muse, mutect2, varscan2
- PLXNA3 | c.4568G>A p.R1523H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151166195, COSV100860113; called by muse, mutect2, varscan2
- PLXNA4 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as rs372562534, COSV58115674; called by muse, mutect2, varscan2
- PM20D1 | c.1441T>C p.F481L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100900219; called by muse, mutect2, varscan2
- POLR3E | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.265); catalogued as rs1440169851, COSV100242264; called by muse, mutect2, varscan2
- POTEE | c.501C>A p.N167K | Missense Mutation (SNP) | VAF 46/390 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as rs1463088057, COSV100388462, COSV100388722; called by muse, mutect2, varscan2
- PRR22 | c.194-8G>A | Splice Region (SNP) | VAF 10/20 reads (50%) | catalogued as rs1056454770, COSV100288361; called by muse, mutect2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs781858060; called by mutect2, varscan2
- PTPN13 | c.3634G>C p.D1212H (on ENST00000411767 / NM_080683.3; = p.D1193H on NM_006264.3) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV100365137; called by muse, mutect2, varscan2
- PUM1 | c.2576A>G p.D859G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928529; called by muse, mutect2, varscan2
- PUM2 | c.1619C>A p.S540Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100163836; called by muse, mutect2, varscan2
- PUM2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV100163837, COSV57580987; called by muse, mutect2, varscan2
- PXDNL | c.3571C>G p.P1191A | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs1460795879, COSV100685023; called by muse, mutect2
- QSOX1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs747164407, COSV62580047; called by muse, mutect2, varscan2
- RAB4B | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100826444; called by mutect2, varscan2
- RAB9B | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54587152, COSV54587397, COSV99686092; called by muse, mutect2, varscan2
- RACK1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV100958650; called by mutect2, varscan2
- RAI2 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100518462; called by muse, mutect2, varscan2
- RANBP2 | c.8857C>T p.R2953C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1269636259, COSV99312113; called by muse, mutect2, varscan2
- RBL2 | c.3305G>C p.R1102T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100043867; called by muse, mutect2, varscan2
- RBM7 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV57784196; called by muse, mutect2, varscan2
- RDH16 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV100660148; called by muse, mutect2, varscan2
- RIBC2 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs1038395496, COSV61581984; called by muse, mutect2, varscan2
- RP1 | c.4743del p.K1581Nfs*7 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | catalogued as COSV99607526; called by mutect2, pindel, varscan2
- RUFY3 | c.178+2T>C p.X60_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99887621; called by muse, mutect2, varscan2
- RYR2 | c.13366G>C p.D4456H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV100771976, COSV63691447; called by muse, mutect2, varscan2
- SATL1 | c.349T>C p.S117P (on ENST00000395409; = p.S304P on NM_001012980.2) | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100260988; called by muse, mutect2, varscan2
- SCAF4 | c.1307C>G p.S436C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54589450; called by muse, mutect2
- SEC16B | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.913); catalogued as COSV100381749; called by muse, mutect2
- SEMA5B | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs746855310, COSV52109459; called by muse, mutect2, varscan2
- SERPINA7 | c.1166G>C p.R389T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100568399; called by muse, mutect2
- SERTAD1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768979696, COSV100781696; called by muse, mutect2, varscan2
- SGTB | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV101121609; called by muse, mutect2, varscan2
- SH3RF1 | c.2605G>T p.G869C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99499268; called by mutect2, varscan2
- SIGLEC7 | c.1124T>C p.V375A | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.024); catalogued as COSV99978835; called by muse, mutect2, varscan2
- SIPA1L1 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV62170914; called by muse, mutect2, varscan2
- SIRT7 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100155477; called by muse, mutect2, varscan2
- SLAIN2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1457153922, COSV99971754; called by muse, mutect2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC17A6 | c.923C>A p.T308K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99581952; called by muse, mutect2, varscan2
- SLC25A41 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); catalogued as COSV51195104; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC45A3 | c.1328A>G p.N443S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs749083178, COSV100901267; called by muse, mutect2, varscan2
- SLC5A10 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185855888, COSV100525322; called by muse, mutect2, varscan2
- SLC6A14 | c.126del p.K42Nfs*8 | Frame Shift Del (DEL) | VAF 21/148 reads (14%) | catalogued as COSV100903217; called by mutect2, pindel, varscan2
- SLC9A2 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372934406; called by muse, mutect2, varscan2
- SLITRK6 | c.2027C>T p.S676L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as COSV101233266; called by muse, mutect2, varscan2
- SMAD4 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs876660045, COSV61684216, COSV61687460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMOX | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99603426; called by mutect2, varscan2
- SNX1 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197690499, COSV99976324; called by muse, mutect2, varscan2
- SPEF2 | c.4789C>T p.L1597F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100289221; called by muse, mutect2, varscan2
- SPNS1 | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100209158, COSV57957107; called by muse, mutect2
- SPON1 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs781858351, COSV100116337; called by muse, mutect2, varscan2
- SPTB | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs776814615, COSV67635244; called by muse, mutect2, varscan2
- SREK1 | c.950G>C p.R317T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs767832773, COSV52334838; called by mutect2, varscan2
- SRGAP2 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); catalogued as rs376951626; called by mutect2, varscan2
- STAG2 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.621); catalogued as COSV99492231; called by muse, mutect2, varscan2
- STAG3 | c.2629T>C p.F877L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV100426092; called by muse, mutect2, varscan2
- STPG1 | c.826G>A p.D276N (on ENST00000337248 / NM_001199013.2; = p.D229N on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV99134252; called by muse, mutect2, varscan2
- TAF1C | c.2512T>C p.S838P | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100499711; called by muse, mutect2, varscan2
- TBL1XR1 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs935282343, COSV100763612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF7 | c.463dup p.H155Pfs*37 | Frame Shift Ins (INS) | VAF 12/55 reads (22%) | catalogued as rs771602751; called by mutect2, varscan2
- TEAD3 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs761773922, COSV100132528; called by muse, mutect2, varscan2
- TENM1 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1223796826, COSV100950448, COSV64438583; called by muse, mutect2, varscan2
- TENM2 | c.6296G>A p.R2099H (on ENST00000518659 / NM_001122679.2; = p.R1860H on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs956087991, COSV101319137, COSV101319541, COSV69144513; called by muse, mutect2, varscan2
- TERB2 | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV100546600; called by muse, mutect2, varscan2
- TET2 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV54419748; called by muse, mutect2, varscan2
- THSD7B | c.4503A>G p.I1501M (on ENST00000272643; = p.I1499M on NM_001316349.2) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99754808; called by muse, mutect2
- TIMM44 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.305); catalogued as rs143337629; ClinVar: uncertain significance; called by mutect2, varscan2
- TIPARP | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1163198135, COSV55815119; called by muse, mutect2, varscan2
- TJAP1 | c.1268C>A p.P423Q (on ENST00000372445 / NM_001146016.1; = p.P413Q on NM_080604.3) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99447038; called by muse, mutect2, varscan2
- TLR7 | c.2728G>C p.A910P | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV101027996; called by muse, mutect2, varscan2
- TM9SF2 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV100899742; called by muse, mutect2, varscan2
- TMC3 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV100845953; called by muse, mutect2, varscan2
- TMEM168 | c.643del p.S215Pfs*19 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as rs762075507; called by pindel, varscan2
- TMEM47 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as COSV99327802; called by muse, mutect2
- TMEM63A | c.2362C>A p.P788T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as COSV99688957; called by muse, mutect2, varscan2
- TMEM86A | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99773809; called by muse, mutect2, varscan2
- TMPRSS3 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as COSV52306173, COSV99368368; called by muse, mutect2, varscan2
- TNXB | c.12200G>A p.R4067H (on ENST00000647633; = p.R3820H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.112); catalogued as rs765400545, COSV100925922, COSV100926460; called by muse, mutect2, varscan2
- TOP1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100793910; called by muse, mutect2, varscan2
- TRAF2 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs200834553, COSV56038604; called by muse, mutect2, varscan2
- TRAP1 | c.1636_1638del p.K546del | In Frame Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs772605434; called by pindel, varscan2
- TRIM62 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as rs929619273, COSV52220532; called by muse, mutect2, varscan2
- TRPA1 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs753381416, COSV100084697; called by muse, mutect2, varscan2
- TTC6 | c.502C>T p.L168F (on ENST00000267368; = p.L1534F on NM_001310135.3) | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99942081; called by muse, mutect2, varscan2
- TTC7A | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs747509395, COSV99766736; called by mutect2, varscan2
- TTN | c.55475C>T p.S18492L (on ENST00000591111; = p.S11068L on NM_003319.4) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | PolyPhen possibly damaging (0.615); catalogued as COSV100621302; called by muse, mutect2, varscan2
- TUBG1 | c.1291C>T p.L431F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99258814; called by muse, mutect2
- TUBGCP6 | c.3958C>T p.R1320W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as rs149423531; called by mutect2, varscan2
- TXNDC15 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100613606; called by muse, mutect2, varscan2
- UBAP2L | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 26/112 reads (23%) | catalogued as COSV99671790; called by muse, mutect2, varscan2
- USH2A | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100238733; called by muse, mutect2, varscan2
- UVSSA | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs148799777; called by mutect2, varscan2
- UVSSA | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as rs199781120; called by muse, mutect2, varscan2
- VRK3 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs745889258, COSV100371623; called by muse, mutect2, varscan2
- VWC2L | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as rs370205207; called by muse, mutect2, varscan2
- WARS1 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV100690244; called by muse, mutect2, varscan2
- WDR62 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54338182, COSV99543936; called by muse, mutect2, varscan2
- XDH | c.1046G>C p.G349A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as rs747404658, COSV101052342, COSV65148400, COSV65151165; called by muse, mutect2, varscan2
- ZBTB45 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as rs750055767, COSV63523051; called by muse, mutect2, varscan2
- ZC3HAV1 | c.705_707del p.S236del | In Frame Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs1331305820; called by pindel, varscan2
- ZFHX4 | c.3497C>T p.S1166F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV99265290; called by muse, mutect2, varscan2
- ZFR2 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs763887729, COSV53602952; called by muse, mutect2, varscan2
- ZMYM6 | c.3041G>A p.R1014H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.972); catalogued as rs1266661656, COSV100593271; called by mutect2, varscan2
- ZNF100 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.249); catalogued as COSV99973856, COSV99974176; called by muse, mutect2, varscan2
- ZNF112 | c.749C>G p.S250* (on ENST00000337401 / NM_001083335.2; = p.S244* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100496053; called by muse, mutect2, varscan2
- ZNF124 | c.1051del p.M351Cfs*19 (on ENST00000543802 / NM_001297568.1; = p.M289Cfs*19 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs755727997; called by mutect2, pindel, varscan2
- ZNF189 | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV99407263; called by muse, mutect2, varscan2
- ZNF506 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV101475646, COSV71354229; called by muse, mutect2, varscan2
- ZNF536 | c.1326C>A p.D442E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); catalogued as COSV100835511; called by muse, mutect2, varscan2
- ZNF579 | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.718); catalogued as rs192618440, COSV100329292, COSV57637582; called by muse, mutect2, varscan2
- ZNF629 | c.2489G>A p.G830E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99354916; called by muse, mutect2, varscan2
- ZNF662 | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs754424406, COSV100066509; called by muse, mutect2, varscan2
- ZNF665 | c.899G>A p.R300Q (on ENST00000600412; = p.R365Q on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs754537311, COSV101128668; called by muse, mutect2, varscan2
- ZNF827 | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as COSV101061533; called by muse, mutect2, varscan2
- ZNF831 | c.153del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs750329558; called by mutect2, varscan2
- ZNF91 | c.2705G>T p.R902I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.203); catalogued as rs747255942, COSV56088409; called by muse, mutect2, varscan2
- ZPBP2 | c.862C>G p.L288V (on ENST00000348931 / NM_199321.3; = p.L266V on NM_198844.3) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.298); catalogued as COSV100818542; called by muse, mutect2, varscan2
- ZSCAN10 | c.1514C>T p.T505M (on ENST00000252463; = p.T560M on NM_032805.3) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs984874719, COSV99374191; called by muse, mutect2
- ARL13A | c.182del p.L61Cfs*2 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- CDC42BPG | c.3784del p.A1262Pfs*68 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- CDHR2 | c.1965dup p.A656Rfs*14 | Frame Shift Ins (INS) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- CNKSR2 | c.1902del p.K634Nfs*24 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | called by mutect2, pindel, varscan2
- CPSF1 | c.3955del p.A1319Pfs*42 | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | called by mutect2, pindel, varscan2
- DDC | c.1297del p.I433Sfs*98 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- DHRS13 | c.1018del p.H340Tfs*23 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- EPB41L1 | c.1635del p.S546Pfs*15 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- FCGBP | c.341_342del p.Y114Cfs*12 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- FPGS | c.528dup p.Y177Lfs*32 | Frame Shift Ins (INS) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- GPC1 | c.541del p.Q181Sfs*71 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- HEPH | c.2220dup p.E741Rfs*9 (on ENST00000343002; = p.E474Rfs*9 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- HP1BP3 | c.394del p.T132Qfs*13 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- HSPBP1 | c.37del p.L13Wfs*55 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | called by mutect2, pindel, varscan2
- KATNIP | c.898del p.Q300Kfs*136 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- KCNC2 | c.158dup p.L54Afs*199 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- LSR | c.1016del p.P339Hfs*4 (on ENST00000361790; = p.P320Hfs*4 on NM_015925.6) | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- MAPK15 | c.642del p.R215Dfs*15 | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- MATN4 | c.1385G>A p.G462D (on ENST00000372754; = p.G421D on NM_003833.4) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | PolyPhen probably damaging (1); called by muse, mutect2
- MCTP1 | c.2177del p.N726Tfs*4 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | called by mutect2, pindel, varscan2
- MEF2B | c.767del p.P256Qfs*28 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- MELK | c.719_721del p.L240del | In Frame Del (DEL) | VAF 16/48 reads (33%) | called by pindel, varscan2
- METTL2B | c.858dup p.M287Dfs*11 | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- MROH2B | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MRPS31 | c.1151dup p.D385Gfs*7 | Frame Shift Ins (INS) | VAF 11/37 reads (30%) | called by mutect2, varscan2
- NXF1 | c.248dup p.D84* | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- OCA2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2
- OR52W1 | c.362del p.L121Wfs*11 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- PCNX3 | c.37dup p.V13Gfs*74 | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- PPA2 | c.779dup p.N260Kfs*7 (on ENST00000341695 / NM_176869.3; = p.N231Kfs*7 on NM_006903.4) | Frame Shift Ins (INS) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- PPAN-P2RY11 | c.369_371del p.S124del | In Frame Del (DEL) | VAF 4/23 reads (17%) | called by pindel, varscan2
- PRKDC | c.10814del p.N3605Tfs*48 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- PSMD11 | c.611del p.P204Lfs*48 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | called by mutect2, pindel, varscan2
- PTGDR | c.198_199del p.C66Wfs*225 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by pindel, varscan2
- PUM1 | c.61del p.H21Tfs*2 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- SLC34A1 | c.1862del p.P621Lfs*61 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- SOCS7 | c.1521C>G p.I507M | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- SPEG | c.2607del p.T870Pfs*11 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- TMTC1 | c.2162dup p.L721Ffs*17 (on ENST00000539277 / NM_001193451.2; = p.L613Ffs*17 on NM_175861.3) | Frame Shift Ins (INS) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- TPTE | c.296T>C p.V99A (on ENST00000618007 / NM_199261.4; = p.V81A on NM_199259.4) | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- TRAV39 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.086); called by muse, mutect2
- TRIM41 | c.738_741del p.C246Wfs*35 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- VCL | c.650del p.N217Tfs*7 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- ZNF512 | c.1235dup p.X412_splice | Splice Site (INS) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- ACAN | c.135C>T p.T45= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs372517447; called by muse, mutect2, varscan2
- ACBD3 | c.1332C>T p.S444= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs763114787, COSV100831082; called by muse, mutect2
- ACSM2A | c.1134C>T p.I378= (on ENST00000219054; = p.I299= on NM_001308169.2) | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99524989, COSV99525474; called by muse, mutect2, varscan2
- ADGRG2 | c.2400G>T p.L800= (on ENST00000379869 / NM_001079858.3; = p.L797= on NM_005756.4) | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100492445; called by muse, mutect2, varscan2
- AFAP1 | c.1638G>A p.T546= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs865904137, COSV100631862; called by muse, mutect2, varscan2
- ALDH2 | c.168C>T p.T56= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99922815; called by muse, mutect2, varscan2
- ALOX15B | c.2028C>T p.I676= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV66480124; called by muse, mutect2
- AOC3 | c.2013A>T p.G671= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99520292; called by muse, mutect2, varscan2
- ARHGAP44 | c.1920T>C p.S640= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV99311132; called by muse, mutect2
- ARID1B | c.6387C>T p.D2129= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs773023212, COSV99270615; called by muse, mutect2, varscan2
- ATP8B2 | c.2982C>T p.G994= (on ENST00000672630; = p.G961= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100528124; called by muse, mutect2, varscan2
- BAHCC1 | c.7128G>A p.S2376= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as rs528624413, COSV100311884; called by muse, mutect2
- BLM | c.3870G>A p.S1290= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV61923956; called by muse, mutect2, varscan2
- BRD4 | c.1143C>T p.D381= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs201519292, COSV99651087; called by muse, mutect2
- C11orf94 | c.132C>T p.S44= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs775621649, COSV53798975, COSV99571611; called by muse, mutect2, varscan2
- C19orf57 | c.612A>G p.S204= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100694769; called by muse, mutect2
- CACNA1S | c.729G>A p.S243= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs148593959, COSV62945501; called by muse, mutect2, varscan2
- CAMTA1 | c.3009C>T p.S1003= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1431634664, COSV100351529; called by muse, mutect2, varscan2
- CC2D1A | c.579G>A p.P193= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs779910927, COSV100528591; called by muse, mutect2, varscan2
- CCDC124 | c.273G>A p.T91= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV101506505; called by muse, mutect2, varscan2
- CCDC60 | c.642G>A p.A214= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs372681245; called by muse, mutect2, varscan2
- CDC42BPA | c.1500A>G p.R500= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1268865281, COSV100506151; called by muse, mutect2, varscan2
- CDH22 | c.81G>A p.P27= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100952939; called by muse, mutect2, varscan2
- CDKL5 | c.2215C>T p.L739= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as rs747554139, COSV101184405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELSR3 | c.8739C>T p.S2913= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs948162683, COSV50855727; called by muse, mutect2
- CNTN5 | c.3216T>C p.S1072= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs1410703771, COSV99679157; called by muse, mutect2, varscan2
- COL4A2 | c.468C>T p.T156= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs765157156, COSV100847420; ClinVar: benign; called by muse, mutect2, varscan2
- COL4A6 | c.3576T>C p.S1192= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100564601; called by muse, mutect2, varscan2
- COL6A2 | c.324C>T p.F108= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100153908; called by muse, mutect2, varscan2
- COL6A2 | c.2199G>C p.G733= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- COPS3 | c.864C>T p.R288= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs370425975; called by muse, mutect2, varscan2
- CREBBP | c.4530G>A p.A1510= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs372936553; called by muse, mutect2, varscan2
- CXXC5 | c.438C>T p.S146= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100210776; called by muse, mutect2, varscan2
- DCAF12L1 | c.117C>T p.L39= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100948377; called by muse, varscan2
- DCN | c.9C>A p.A3= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99272459; called by muse, mutect2, varscan2
- DMBT1 | c.7086T>C p.N2362= (on ENST00000338354 / NM_001377530.1; = p.N1605= on NM_004406.3) | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100353602; called by muse, mutect2, varscan2
- DNASE2 | c.1017G>A p.P339= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs201271441, COSV99263311; called by muse, mutect2, varscan2
- DTX4 | c.1320C>T p.C440= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs753418892, COSV99915703; called by muse, mutect2, varscan2
- EPS15 | c.396T>C p.Y132= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as rs1287522103, COSV100869071; called by muse, mutect2
- EPS8L3 | c.1377C>T p.Y459= (on ENST00000361965 / NM_133181.4; = p.Y429= on NM_024526.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs546054799, COSV100719731; called by muse, mutect2, varscan2
- EPX | c.912G>A p.A304= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs753929272, COSV99836652; called by muse, mutect2, varscan2
- FAM122A | c.363C>T p.F121= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1267563790, COSV55254613; called by muse, mutect2, varscan2
- FAM47B | c.1659C>T p.F553= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs1445597831, COSV61453228; called by muse, mutect2, varscan2
- FBXW9 | c.495C>T p.S165= (on ENST00000587955; = p.S175= on NM_032301.3) | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs572407173, COSV100790387; called by muse, mutect2
- FCGBP | c.10488C>T p.D3496= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as rs771508776; called by muse, mutect2, varscan2
- FCRL3 | c.2193C>A p.A731= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100943426; called by muse, mutect2, varscan2
- FN3KRP | c.666C>T p.N222= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs1346759335, COSV53931746, COSV99485055; called by muse, mutect2
- GNPTAB | c.2919C>T p.F973= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs991497373, COSV100172200; called by muse, mutect2, varscan2
- GRIN2D | c.1233C>G p.L411= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99616723; called by muse, mutect2, varscan2
- GRM5 | c.2244A>T p.G748= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100553224; called by muse, mutect2, varscan2
- HDHD5 | c.999G>A p.T333= (on ENST00000336737 / NM_033070.3; = p.T303= on NM_017829.5) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1477284020, COSV50084976; called by muse, mutect2, varscan2
- HSD17B2 | c.1110C>T p.D370= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV52275534, COSV52276968; called by muse, mutect2, varscan2
- INPP5K | c.870G>A p.A290= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs766956300, COSV100233848; called by muse, varscan2
- IPO5 | c.2964C>T p.N988= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99847299; called by muse, mutect2, varscan2
- IRF4 | c.192C>T p.R64= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV101110916; called by muse, mutect2, varscan2
- ITGB1BP2 | c.231C>T p.G77= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs759901456, COSV99339004; called by muse, mutect2, varscan2
- KALRN | c.2133G>A p.A711= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs771916960, COSV53760606; called by muse, mutect2, varscan2
- KCNJ8 | c.87C>T p.D29= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99557655; called by muse, mutect2, varscan2
- KIAA1328 | c.909T>C p.S303= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99694803; called by muse, mutect2
- LAMA2 | c.3075A>G p.P1025= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV101370646; called by muse, mutect2, varscan2
- LMTK3 | c.1248T>C p.P416= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1247348875, COSV54312366; called by muse, varscan2
- LRG1 | c.297C>G p.L99= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100014985; called by muse, mutect2, varscan2
- LRP1B | c.8898T>C p.C2966= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV101258266; called by muse, mutect2
- MAN1A1 | c.1215T>C p.H405= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100870704; called by muse, mutect2, varscan2
- MOB3A | c.120C>T p.N40= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs749697378, COSV100830057; called by muse, mutect2, varscan2
- MRGPRX1 | c.240T>G p.L80= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100246096, COSV57106467; called by muse, mutect2, varscan2
- MS4A13 | c.96T>A p.T32= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100981056; called by muse, mutect2, varscan2
- MTMR1 | c.1689G>A p.S563= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs782544420, COSV64892575; called by muse, mutect2
- MTTP | c.2235T>C p.S745= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99645407; called by muse, mutect2
- MYH8 | c.4404T>C p.A1468= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV101238516, COSV67959919; called by muse, mutect2, varscan2
- MYRF | c.2361C>T p.Y787= (on ENST00000278836 / NM_001127392.3; = p.Y778= on NM_013279.4) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs768090204; called by muse, mutect2, varscan2
- NEB | c.9378C>T p.V3126= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99425567; called by muse, mutect2, varscan2
- NFATC2 | c.2544G>A p.P848= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs546062557, COSV65362787; called by muse, mutect2, varscan2
- NOS3 | c.3486C>T p.L1162= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs1351506130, COSV99871914; called by muse, mutect2, varscan2
- NUCB1 | c.1041G>A p.L347= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV54387814; called by mutect2, varscan2
- OBSCN | c.23145C>T p.R7715= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1410691196, COSV100804818; called by muse, mutect2, varscan2
- OCM | c.330A>G p.*110= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99631483; called by muse, mutect2, varscan2
- OR11A1 | c.732C>T p.S244= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV101010719; called by muse, mutect2, varscan2
- OR8B3 | c.174A>G p.P58= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV63541855; called by muse, mutect2
- PAAF1 | c.129T>C p.I43= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV100142578; called by muse, mutect2
- PABPC1L | c.1848G>A p.A616= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs377541297; called by muse, mutect2, varscan2
- PAK5 | c.702C>T p.F234= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100781545; called by muse, mutect2, varscan2
- PARP10 | c.162C>T p.L54= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs949764974, COSV57300212, COSV57300263; called by muse, mutect2, varscan2
- PCDHGA12 | c.213G>A p.R71= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99341329; called by muse, mutect2, varscan2
- PCIF1 | c.1536C>T p.F512= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs753235115, COSV59816052; called by muse, mutect2, varscan2
- PDE7A | c.654G>A p.A218= (on ENST00000401827 / NM_001242318.3; = p.A192= on NM_002603.4) | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs763637723, COSV65154103; called by muse, mutect2, varscan2
- PDE8B | c.867C>T p.H289= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1322898883, COSV99366419; called by muse, mutect2, varscan2
- PHKA2 | c.201C>T p.R67= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs746817651, COSV66055430; called by mutect2, varscan2
- PIAS4 | c.921G>C p.L307= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99518978; called by muse, mutect2, varscan2
- PKHD1 | c.10104T>C p.V3368= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100583835; called by muse, mutect2, varscan2
- PLA2G6 | c.438C>T p.C146= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs749236337, COSV100140589; called by muse, mutect2, varscan2
- PLD4 | c.1203G>A p.A401= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs928173825, COSV101190535; called by muse, mutect2, varscan2
- POGZ | c.189G>A p.G63= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99653043; called by muse, mutect2, varscan2
- PPP1R16A | c.1554C>T p.P518= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs370667216; called by muse, mutect2, varscan2
- PRTFDC1 | c.372C>T p.I124= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs758689861, COSV60774058, COSV60776048; called by muse, mutect2, varscan2
- PTGDR2 | c.501C>T p.F167= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs777347417, COSV99920200; called by muse, mutect2, varscan2
- PTPRF | c.3612G>A p.K1204= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs1018260007, COSV100741057; called by muse, varscan2
- PTPRG | c.984C>T p.H328= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs747299296, COSV99876021; called by muse, mutect2, varscan2
- RALGAPB | c.2193G>A p.E731= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99485490; called by mutect2, varscan2
- RBM3 | c.39C>G p.L13= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100618766; called by muse, mutect2, varscan2
- RBMS1 | c.222C>T p.T74= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs756456331, COSV100816965; called by muse, mutect2, varscan2
- RBP4 | c.192C>T p.S64= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101012287; called by muse, mutect2, varscan2
- RICTOR | c.3951T>C p.C1317= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99705398; called by muse, mutect2
- RNF2 | c.987C>T p.Y329= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs1471212169, COSV100835779, COSV62280671; called by muse, mutect2, varscan2
- RSAD1 | c.414G>A p.P138= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs780208296, COSV51955731; called by muse, mutect2, varscan2
- RYR2 | c.1851C>G p.L617= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100771975; called by muse, mutect2
- SBNO1 | c.1275C>T p.C425= (on ENST00000420886; = p.C424= on NM_018183.5) | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs116030405; called by muse, mutect2, varscan2
- SEC31A | c.1347G>A p.V449= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100021766; called by muse, mutect2, varscan2
- SEMA4A | c.2250C>T p.D750= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs780054588, COSV100740667; called by mutect2, varscan2
- SHANK1 | c.2412G>A p.P804= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs776918094, COSV99521642; called by muse, mutect2, varscan2
- SHC1 | c.156C>T p.D52= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV100460482, COSV58316536; called by muse, mutect2
- SLC12A5 | c.1338C>T p.D446= (on ENST00000454036 / NM_001134771.2; = p.D423= on NM_020708.5) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99716453; called by muse, mutect2, varscan2
- SLC26A4 | c.1752G>A p.A584= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs771015634, COSV55914542; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC45A2 | c.1563T>C p.F521= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99672929; called by muse, mutect2, varscan2
- SLC6A3 | c.69C>T p.A23= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs145257591; called by muse, mutect2
- SOCS7 | c.1302C>T p.S434= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- SPAG1 | c.1734G>A p.E578= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV99309255; called by muse, mutect2, varscan2
- SPATA31E1 | c.285C>T p.P95= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs762786546, COSV100350752; called by muse, mutect2, varscan2
- STAR | c.558C>T p.S186= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs757825631, COSV52418306; called by muse, mutect2, varscan2
- TBC1D2 | c.387G>A p.A129= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs371810743; called by muse, mutect2, varscan2
- TCF7L1 | c.1491G>A p.S497= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs771494952, COSV56400978; called by muse, mutect2, varscan2
- TEDC2 | c.471G>A p.L157= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV99563886; called by muse, mutect2, varscan2
- TJP2 | c.2859G>A p.S953= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs369972534, COSV99601379; called by muse, mutect2, varscan2
- TMCC1 | c.165C>G p.L55= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV67874268; called by mutect2, varscan2
- TMEM236 | c.75C>G p.L25= | Silent (SNP) | VAF 48/139 reads (35%) | called by muse, mutect2, varscan2
- TMTC1 | c.609C>T p.F203= (on ENST00000539277 / NM_001193451.2; = p.F95= on NM_175861.3) | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99760321; called by muse, varscan2
- TNFRSF14 | c.405C>T p.C135= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs587778716, COSV100859192; ClinVar: not provided; called by muse, mutect2, varscan2
- TNRC18 | c.3135C>T p.I1045= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1205923168, COSV101269792; called by muse, mutect2
- TREH | c.645C>T p.R215= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs781966736, COSV99874641; called by muse, mutect2, varscan2
- TRIM21 | c.120C>T p.I40= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1162778222, COSV99587796; called by mutect2, varscan2
- TTC14 | c.36C>T p.C12= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV99932207; called by muse, mutect2
- TUBA1B | c.279C>A p.I93= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs768531356, COSV100254182; called by muse, mutect2, varscan2
- TYK2 | c.3471C>A p.S1157= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV53391269, COSV99315054; called by muse, mutect2, varscan2
- WASHC5 | c.2151C>T p.R717= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs766145087, COSV100572410; called by muse, mutect2, varscan2
- WDR93 | c.1479C>T p.D493= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs760843965, COSV99175714; called by muse, mutect2, varscan2
- ZFHX3 | c.9435G>A p.T3145= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs944027642, COSV99213762; called by muse, mutect2, varscan2
- ZNF43 | c.429C>T p.S143= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV61686474; called by muse, mutect2
- AFF1 | c.1038+76G>A | Intron (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2
- AL132655.6 | chr20:58840598 C>T | 5'Flank (SNP) | VAF 10/70 reads (14%) | catalogued as rs772893248, COSV100007114, COSV58344693; called by muse, mutect2, varscan2
- ATG16L1 | c.1204-942C>T | Intron (SNP) | VAF 19/68 reads (28%) | catalogued as rs1283359322, COSV100731352; called by muse, mutect2, varscan2
- DDC | c.944+2404T>C | Intron (SNP) | VAF 4/51 reads (8%) | catalogued as COSV100779626; called by muse, mutect2
- DDN | c.*1G>A | 3'UTR (SNP) | VAF 5/29 reads (17%) | catalogued as COSV101373628; called by muse, mutect2, varscan2
- DNAJC11 | c.*891G>T | 3'UTR (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99275810; called by muse, mutect2, varscan2
- DPP6 | c.*472C>T | 3'UTR (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100124659; called by muse, mutect2, varscan2
- GPC3 | c.1033-4213T>C | Intron (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100893309; called by muse, mutect2, varscan2
- LEKR1 | c.*1231C>T | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- MARCHF1 | c.-322-85814T>C | Intron (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- MIR222 | n.59C>T | RNA (SNP) | VAF 24/144 reads (17%) | catalogued as rs187612279; called by muse, mutect2, varscan2
- SYNE2 | c.19333+876C>T | Intron (SNP) | VAF 5/23 reads (22%) | catalogued as rs762635611, COSV59943997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.10360+4758C>T | Intron (SNP) | VAF 14/38 reads (37%) | catalogued as rs528405503, COSV100621303; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451383 C>T | 5'Flank (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99989988; called by muse, mutect2
- ZNF99 | c.*282G>A | 3'UTR (SNP) | VAF 11/40 reads (28%) | catalogued as COSV68057962; called by muse, mutect2, varscan2
